Surgical pathology report (de-identified scan), TCGA case TCGA-30-1714, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Harvard, specimen TCGA-30-1714-01A (Primary Tumor).

[page 1 of 3]
Accession Number: [REDACTED] Report Status: Final

Type: Surgical Pathology

Pathology Report [REDACTED] OMENTUM BIOPSY

Accessioned On: [REDACTED]

TCGA-30-1714

DIAGNOSIS:

SPECIMEN LABELED "OMENTAL BIOPSY":

Adipose tissue with focal chronic inflammation and mesothelial hyperplasia.

SPECIMEN LABELED "LEFT ADNEXAL MASS" [REDACTED]:

PAPILLARY SEROUS ADENOCARCINOMA, grade 3 of 3, involving the ovary and extending to the surface of the tumor mass.

Tumor involves the serosal surface of adjacent fallopian tube.

Lymphovascular invasion not identified.

SPECIMEN LABELED "RIGHT TUBE AND OVARY" (including FSB):

PAPILLARY SEROUS ADENOCARCINOMA, grade 3 of 3, involving the ovary and extending to the ovarian surface.

Tumor involves fimbria of adjacent fallopian tube.

Lymphovascular invasion not identified.

Fallopian tube with extensive tubo-ovarian adhesions.

SPECIMEN LABELED "RADIAL HYSTERECTOMY" (67g):

METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA involving uterine serosa, and parametrial and paracervical soft tissue.

Cervix with no significant pathologic change.

Atrophic endometrium with endocervical polyp.

Myometrium with no significant pathologic change.

SPECIMEN LABELED "TUMOR MASS LEFT URETER":

METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA.

SPECIMEN LABELED "TUMOR FROM RECTO-SIGMOID":

METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA.

SPECIMEN LABELED "LEFT EXTERNAL ILIAC NODE":

One (1) lymph node with METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA.

SPECIMEN LABELED "TUMOR FROM UPPER SIGMOID":

METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA.

CLINICAL DATA:

History: [REDACTED] G4, P3 with pelvic mass.

None given.

Clinical Diagnosis: Pelvic mass

TISSUE SUBMITTED: 1. Omental biopsy

2. Adnexal mass (FSA)

3. Right tube & ovary (FSB)

4. Radical hysterectomy

5. Tumor near left ureter

6. Tumor from recto sigmoid

7. Left external iliac node

8. Tumor from upper sigmoid

O.R. CONSULTATION:

SPECIMEN LABELED "#2 LEFT ADNEXAL MASS" (FSA):

Consistent with serous adenocarcinoma.

[page 2 of 3]
SPECIMEN LABELED "#3 RIGHT ADNEXAL MASS" (FSB):

Consistent with serous adenocarcinoma.

GROSS DESCRIPTION:

The specimen is received fresh in eight parts, each labeled with the patient's name and unit number.

Part one, "omental biopsy", consists of a single fragment of yellow/pink adipose tissue consistent with omentum (24 x 13 x 1.5 cm). No suspicious nodules or other lesions are identified. Representative sections are submitted.

Micro sections:

Micro 1-8: omental biopsy, 24 frags, [REDACTED]

TCGA-30-1714

Part two, "left adnexal mass", consists of a lobulated, partially disrupted tan/pink firm mass (8.0 x 7.0 x 3.5 cm), with attached fallopian tube (4.0 cm length by 0.8 cm maximum diameter). The surface of the mass that is not disrupted is encapsulated, with a tan/white, smooth and glistening surface and foci of tan/pink nodules (largest area 2.1 cm in greatest dimension), adjacent to the disrupted areas. Cross sections reveal a tan/pink, loosely adherent fungating mass with foci of hemorrhage, no residual ovarian tissue identified. The attached fallopian tube is unremarkable, and is within 0.5 cm of the tumor mass. A representative section of a papillary portion of tumor mass was evaluated intraoperatively, and the remnant is submitted as FSA. Additional representative histologic sections are also submitted.

Micro 9: frozen section A remnant, 1 frag, [REDACTED]

Micro 10-13: tumor and capsule, 6 frags, [REDACTED]

Micro 14: tumor at solid area with possible ovarian tissue, 1 frag, [REDACTED]

Micro 15: tumor adjacent to fallopian tube and fallopian tube resection margin, 2 frags, [REDACTED]

Micro 16: additional fallopian tube, 2 frags, [REDACTED]

Part three, "right adnexal mass", consists of a tan/pink firm lobulated mass (5.5 x 4.0 x 3.0 cm), and attached pink/tan fallopian tube (4.5 cm in length by 0.7 cm in maximum diameter). The surface of the mass is smooth and glistening, except for a puckered area opposite the fallopian tube attachment (1.5 x 1.5 cm), with an associated tan/pink nodule on the surface. On cut section, the mass is tan/white, solid, with a central hemorrhagic cyst (2.0 cm in greatest dimension). There is also a larger serous fluid-filled simple cyst (3.5 cm in greatest dimension). No definite residual ovarian tissue is identified. Projecting from the fimbriated end of the fallopian tube is a fungating tan/white mass (2.5 x 1.5 x 1.5 cm). The more distal portion of the tube is unremarkable. A portion of the solid mass is evaluated intraoperatively and submitted as FSB, and additional representative sections are submitted.

Micro 17: frozen section B remnant, 1 frag, [REDACTED]

Micro 18-19: solid areas of tumor (including surface nodule in 18), 2 frags, [REDACTED]

Micro 20-23: solid and cystic areas, 4 frags, [REDACTED]

Micro 24: fallopian tube and fimbriae with mass, 2 frags, [REDACTED]

Micro 25: additional fallopian tube, 3 frags, [REDACTED]

Part four, "radical hysterectomy", consists of a 67 gm radical hysterectomy specimen, including cervix, uterus and attached soft tissue. The uterus measures 4.5 x 4.5 x 3.0 cm and has two areas of nodularity on the serosal surface, including one area on the posterior surface near the right horn (2.5 x 2.0 cm), and another area posteriorly near the cervix (1.5 x 1.0 cm). These nodular areas are associated with tan/white solid tumor masses that are present on the serosal surface, but do not penetrate into the underlying myometrium, which is unremarkable (1.1 cm in maximum thickness). The endometrium (2.0 cm from cornu to cornu by 3.5 cm in length) is smooth and glistening, and is distorted by a tan endometrial polyp (1.0 x 0.7 x 0.4 cm) near the left cornu. The tan, smooth and glistening focally hemorrhagic exocervix (3.0 cm diameter) has a tight, circular os (0.2 cm in diameter). The endocervix (3.2 cm in length by 1.1 cm in width) has a smooth, herringbone-like mucosal surface. Soft tissue masses emanate bilaterally from

[page 3 of 3]
the cervix (5.0 x 3.0 x 1.5 cm on the left, and 3.0 x 2.5 x 1.0 cm on the right), and both contain firm, tan/white tumor nodules (largest 2.0 cm in greatest dimension). Representative sections are submitted.

Micro 26: anterior cervix, 1 frag, [REDACTED]
Micro 27: posterior cervix and posterior LUS with firm nodule, 2 frags [REDACTED]
Micro 28: anterior endometrium with polyp and serosa, 4 frags, [REDACTED]
Micro 29: posterior endometrium with serosal nodule, 1 frag, [REDACTED]
Micro 30: soft tissue nodule in left, 1 frag, [REDACTED]
Micro 31: soft tissue nodule in right, 1 frag, [REDACTED]

TCGA-30-1714

Part five, "tumor near left ureter", consists of three fragments of irregular, cauterized tan/pink fibrous tissue (3.0 x 2.0 x 1.0 cm, 1.8 x 1.2 x 0.6 cm and 1.1 x 0.6 x 0.5 cm). All three fragments are infiltrated with firm, tan/white tumor. Representative sections of each are submitted.

Micro 32: tumor near left ureter, 3 frags, [REDACTED]

Part six, "tumor from recto sigmoid", consists of five fragments of irregular tan/pink firm and fibrous tissue (2.3 x 1.2 x 0.5 cm in aggregate). The specimen is entirely submitted.

Micro 33: tumor from recto sigmoid, 5 frags, [REDACTED]

Part seven, "left external iliac node", consists of a single fragment of tan/pink/yellow firm fibroadipose tissue (1.5 x 1.2 x 1.0 cm). The specimen is trisected and entirely submitted.

Micro 34: left external iliac node, 3 frags, [REDACTED]

Part eight, "upper sigmoid nodule", consists of multiple fragments (approximately eight) of tan/pink fibrous tissue (2.2 x 1.8 x 0.4 cm in aggregate). The specimen is entirely submitted.

Micro 35: upper sigmoid nodule, multiple frags, [REDACTED]

Reports to: [REDACTED]

SPECIMEN TYPE: OMENTUM BIOPSY

ADDITIONAL SPECIMEN TYPE: UTERUS WITH OR WITHOUT TUBES & OVARIES, NEOPLASTIC

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE BIOPSY

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE BIOPSY

ADDITIONAL SPECIMEN TYPE: LYMPH NODE BIOPSY

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE BIOPSY

Source: NCI Genomic Data Commons file 5154bfe2-551a-4f0d-b44e-c41630775163 (TCGA-30-1714.7BEC7160-E40C-4B47-B0D6-93652C5E27F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).